Somatic mutation profile of tumor specimen TCGA-YD-A89C-06A (aliquot TCGA-YD-A89C-06A-11D-A372-08) from TCGA case TCGA-YD-A89C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.8 years (16,006 days).
Specimen TCGA-YD-A89C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05db37b7-6261-48c1-b5df-d1f3acc0bebe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YD-A89C-10A (Blood Derived Normal), aliquot TCGA-YD-A89C-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cf5bf0c-a5d8-4939-9438-cf8ac4bf9091

The open-access MAF lists 2,066 somatic variants for this specimen: 1,340 protein-altering or splice-affecting, 677 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,210, Silent 677, Nonsense Mutation 84, Intron 21, Splice Site 18, Splice Region 17, RNA 16, 3'UTR 8, Frame Shift Del 5, Translation Start Site 3, 5'UTR 2, In Frame Del 2.

Variants (750 of 2,066; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.9730C>T p.R3244* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as rs199422195, CM077231, COSV54130194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 42/113 reads (37%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906616, CM066837, COSV99247178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NLGN3 | c.1600C>T p.P534S (on ENST00000358741 / NM_181303.2; = p.P514S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1569485503, COSV100704948; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 45/127 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 127/252 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by muse, mutect2, varscan2
- A1CF | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV99256102; called by muse, mutect2, varscan2
- AADACL3 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1208910089, COSV60200228; called by muse, mutect2, varscan2
- AADACL4 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV100879478; called by muse, mutect2, varscan2
- ABCA1 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs551884479, CM1210656, COSV66064183; called by muse, mutect2, varscan2
- ABCB1 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773175021, COSV99713809; called by muse, mutect2, varscan2
- ABCB5 | c.2500G>A p.G834R (on ENST00000404938 / NM_001163941.2; = p.G389R on NM_178559.6) | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs1417398661, COSV99329128; called by muse, mutect2, varscan2
- ABCB9 | c.1577C>T p.S526F (on ENST00000280560 / NM_019625.4; = p.S483F on NM_019624.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54892722; called by muse, mutect2, varscan2
- ABCC2 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as rs765749316, COSV64988539; called by muse, mutect2, varscan2
- ABCC4 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100972669; called by muse, mutect2, varscan2
- ABCC9 | c.2675G>A p.R892K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53962436; called by muse, mutect2, varscan2
- ABCD4 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs945270666, COSV100084442; called by muse, mutect2, varscan2
- ABRA | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs148182297, COSV61733215; called by muse, mutect2, varscan2
- ACAN | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs148018909, COSV100717370, COSV61358645; called by muse, mutect2
- ACAN | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1305675214, COSV100718845; called by muse, mutect2, varscan2
- ACAN | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs867650450, COSV100718847; called by muse, varscan2
- ACAN | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs376237216, COSV61355063; called by muse, mutect2, varscan2
- ACSBG1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV99357673; called by muse, mutect2, varscan2
- ACSM2A | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99525519; called by muse, mutect2, varscan2
- ACSM2A | c.1163C>T p.S388F (on ENST00000219054; = p.S309F on NM_001308169.2) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs866827349, COSV99525520; called by muse, varscan2
- ACSM3 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as rs1477758010, COSV99184806; called by muse, mutect2
- ACSS3 | c.1820-1G>A p.X607_splice | Splice Site (SNP) | VAF 33/94 reads (35%) | catalogued as COSV54085802, COSV99699261; called by muse, mutect2, varscan2
- ACTL9 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.233); catalogued as rs1555753494, COSV100185484; called by muse, mutect2, varscan2
- ADAD1 | c.1474A>T p.K492* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV99636053; called by muse, mutect2, varscan2
- ADAM12 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781093872, COSV100901075, COSV64111680; called by muse, varscan2
- ADAM18 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV55847632; called by muse, mutect2, varscan2
- ADAM18 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs865870698, COSV55844130; called by muse, mutect2, varscan2
- ADAM30 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101023932; called by muse, mutect2, varscan2
- ADAMTS13 | c.3749G>A p.W1250* | Nonsense Mutation (SNP) | VAF 16/23 reads (70%) | catalogued as COSV99390395; called by muse, mutect2, varscan2
- ADAMTS13 | c.3750G>A p.W1250* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as COSV99390396; called by muse, mutect2, varscan2
- ADAMTS16 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193968598, COSV56992843; called by muse, mutect2, varscan2
- ADAMTS17 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV99171363; called by muse, mutect2
- ADAMTS20 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143824237; called by muse, mutect2, varscan2
- ADAMTS3 | c.2910G>A p.W970* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99711738; called by muse, mutect2, varscan2
- ADAMTS7 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183201; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4225G>A p.D1409N | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101000518; called by muse, mutect2, varscan2
- ADAMTSL4 | c.530G>C p.S177T | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99647689; called by muse, mutect2, varscan2
- ADAP2 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as COSV100437328; called by muse, mutect2, varscan2
- ADCY8 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.147); catalogued as COSV53934686; called by muse, mutect2
- ADCY8 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99653531; called by muse, mutect2, varscan2
- ADCY9 | c.1208T>G p.F403C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570547; called by muse, mutect2, varscan2
- ADGRG4 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99796245; called by muse, mutect2, varscan2
- ADGRG4 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV104381503, COSV54960601, COSV54968673; called by muse, mutect2, varscan2
- ADGRG7 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs909433668, COSV56293550; called by muse, mutect2, varscan2
- ADGRL2 | c.3817C>G p.R1273G (on ENST00000370717 / NM_001366005.1; = p.R1217G on NM_012302.4) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99590582; called by muse, mutect2, varscan2
- ADGRV1 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.649); catalogued as COSV101316278; called by muse, mutect2
- ADH7 | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99265052, COSV99265221; called by muse, mutect2, varscan2
- ADPRM | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV101126095; called by muse, mutect2, varscan2
- AFAP1L2 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100412844; called by muse, mutect2, varscan2
- AFF2 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99665511; called by muse, mutect2, varscan2
- AFM | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV56921495; called by muse, mutect2, varscan2
- AFM | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889043; called by muse, mutect2, varscan2
- AGAP6 | c.519T>A p.V173= (on ENST00000374056 / NM_001365867.1; = p.V196= on NM_001077665.2) | Splice Region (SNP) | VAF 34/120 reads (28%) | catalogued as COSV100929113; called by mutect2, varscan2
- AGBL5 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs754070994, COSV100549281; called by muse, mutect2, varscan2
- AHNAK | c.1019A>T p.H340L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.275); catalogued as COSV99948805; called by muse, mutect2, varscan2
- AHNAK2 | c.13415C>T p.S4472F | Missense Mutation (SNP) | VAF 139/362 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100318456; called by muse, mutect2, varscan2
- AHNAK2 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as rs372755911; called by muse, mutect2, varscan2
- AIF1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as rs756309139, COSV100559080; called by muse, mutect2, varscan2
- AKAP14 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100538372; called by muse, mutect2, varscan2
- AKAP4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs147442985, COSV62073813; called by muse, mutect2, varscan2
- AKNAD1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1322240847, COSV100645761; called by muse, mutect2, varscan2
- ALG1L | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.465); catalogued as rs1223526717, COSV100444874; called by muse, mutect2, varscan2
- ALMS1 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 99/200 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as rs767763496, COSV100043264; called by muse, mutect2, varscan2
- ALMS1 | c.5444C>T p.S1815F | Missense Mutation (SNP) | VAF 156/281 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.106); catalogued as rs528863432, COSV52517109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.12253G>A p.E4085K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV100043267; called by muse, mutect2, varscan2
- ALOX15B | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs772792324, COSV101205670; called by muse, mutect2, varscan2
- ALPK2 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs771196152, COSV64496773; called by muse, mutect2, varscan2
- ALPK3 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV51931373; called by muse, mutect2, varscan2
- AMER1 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs754938624, COSV57658266; called by muse, mutect2, varscan2
- AMER1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as COSV100366292, COSV100366806; called by muse, mutect2, varscan2
- AMFR | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99316124; called by muse, mutect2, varscan2
- ANAPC1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs868008388, COSV61975180; called by muse, mutect2, varscan2
- ANGPT1 | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52442537; called by muse, mutect2, varscan2
- ANGPTL1 | c.1289-1G>A p.X430_splice | Splice Site (SNP) | VAF 31/121 reads (26%) | catalogued as COSV99328313; called by muse, mutect2, varscan2
- ANGPTL4 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100035214; called by muse, mutect2, varscan2
- ANK3 | c.7925C>T p.S2642F | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV99781455; called by muse, mutect2, varscan2
- ANK3 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99781457; called by muse, mutect2, varscan2
- ANKRD28 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as rs1559436859, COSV67519334; called by muse, mutect2, varscan2
- ANO4 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54585481; called by muse, mutect2, varscan2
- ANO4 | c.2315G>A p.G772E (on ENST00000392977 / NM_001286615.2; = p.G737E on NM_178826.4) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs866052988, COSV54589756; called by muse, mutect2, varscan2
- ANO5 | c.749A>T p.Y250F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100202056, COSV61089564; called by muse, mutect2, varscan2
- ANOS1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV52915386, COSV99391230; called by muse, mutect2, varscan2
- APOA4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs145184607; called by muse, mutect2, varscan2
- APOB | c.12445C>T p.Q4149* | Nonsense Mutation (SNP) | VAF 51/163 reads (31%) | catalogued as COSV99266993; called by muse, mutect2, varscan2
- APOBEC3G | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs367793502; called by muse, mutect2, varscan2
- APOC4 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs764998450, COSV99377017; called by muse, mutect2, varscan2
- APOL1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100046287; called by muse, mutect2, varscan2
- APOL6 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101291009; called by mutect2, varscan2
- ARFGEF2 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100904381; called by muse, mutect2, varscan2
- ARFIP2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1182306335, COSV99601490; called by muse, mutect2, varscan2
- ARGFX | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV57681751; called by muse, mutect2, varscan2
- ARHGAP32 | c.4651C>T p.P1551S (on ENST00000310343 / NM_001378025.1; = p.P1202S on NM_014715.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as COSV100088628; called by muse, mutect2, varscan2
- ARHGAP33 | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV50123381; called by muse, mutect2, varscan2
- ARHGAP36 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.109); catalogued as COSV52266997, COSV99358025; called by muse, mutect2, varscan2
- ARHGAP6 | c.2707G>C p.G903R (on ENST00000337414 / NM_013427.3; = p.G700R on NM_013423.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.047); catalogued as COSV100273376; called by muse, mutect2, varscan2
- ARHGAP9 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV99954440; called by muse, mutect2, varscan2
- ARHGEF10 | c.3703C>T p.P1235S (on ENST00000398564; = p.P1210S on NM_014629.4) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV50642911; called by muse, mutect2, varscan2
- ARHGEF15 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100730109; called by muse, mutect2, varscan2
- ARHGEF37 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100382252; called by muse, mutect2, varscan2
- ARHGEF5 | c.586A>C p.N196H | Missense Mutation (SNP) | VAF 115/517 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV99283066; called by muse, mutect2, varscan2
- ARMC2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV52901634; called by muse, mutect2
- ARMC4 | c.135T>A p.H45Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100537190; called by muse, mutect2, varscan2
- ARSH | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101139951; called by muse, mutect2
- ASB15 | c.160+1G>A p.X54_splice | Splice Site (SNP) | VAF 25/86 reads (29%) | catalogued as COSV99306849; called by muse, mutect2, varscan2
- ASPHD1 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 29/51 reads (57%) | catalogued as rs757323827, COSV58100198; called by muse, mutect2, varscan2
- ASXL3 | c.4842G>A p.M1614I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1221086390, COSV52465484, COSV99325914; called by muse, mutect2
- ATAD2B | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778698296, COSV53203780; called by muse, mutect2, varscan2
- ATCAY | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100008930; called by muse, mutect2, varscan2
- ATN1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100755900; called by muse, mutect2, varscan2
- ATP12A | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 222/379 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV54515876; called by muse, mutect2, varscan2
- ATP13A4 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.58); catalogued as COSV99795013; called by muse, mutect2, varscan2
- ATP2A2 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as rs370067725; called by muse, mutect2, varscan2
- ATP6AP2 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101011432, COSV65797478; called by muse, mutect2, varscan2
- ATP9A | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1183526175, COSV58765373; called by muse, varscan2
- AXDND1 | c.1230G>A p.K410= | Splice Region (SNP) | VAF 35/146 reads (24%) | catalogued as COSV100858556; called by muse, mutect2, varscan2
- AXDND1 | c.2115G>A p.M705I | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62642676; called by muse, mutect2, varscan2
- AXDND1 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100858558, COSV62640716; called by muse, mutect2, varscan2
- AXL | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99996979; called by muse, mutect2, varscan2
- B3GNT3 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs769736671, COSV57953699; called by muse, mutect2
- B3GNT3 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1555740477, COSV57952806; called by muse, mutect2
- B4GALNT2 | c.1151G>A p.R384K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100302688; called by muse, mutect2, varscan2
- BCAT2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as COSV60273040; called by muse, mutect2, varscan2
- BCL11A | c.685C>T p.P229S (on ENST00000335712 / NM_001365609.1; = p.P263S on NM_018014.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs946244619, COSV59623842, COSV59637975; called by muse, mutect2, varscan2
- BCL11B | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100595750, COSV61735124; called by muse, mutect2, varscan2
- BEST3 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100437904; called by muse, mutect2, varscan2
- BLNK | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV99814111; called by muse, mutect2, varscan2
- BMP10 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV99770530; called by muse, mutect2, varscan2
- BMP2K | c.2733A>C p.E911D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99785333; called by muse, mutect2, varscan2
- BMP5 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV100896202; called by muse, mutect2, varscan2
- BNC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs968421847, COSV61756810; called by muse, mutect2, varscan2
- BNC1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61758856; called by muse, mutect2, varscan2
- BNC1 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100597371; called by muse, mutect2, varscan2
- BPIFB2 | c.923T>C p.F308S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99401577; called by muse, varscan2
- BPIFB4 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.13); catalogued as COSV100971613; called by muse, mutect2, varscan2
- BRCA2 | c.3276T>A p.F1092L | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV101204533; called by muse, mutect2, varscan2
- BRD2 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.152); catalogued as rs377684930, COSV100875781; called by muse, mutect2, varscan2
- BRINP2 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV64176770; called by muse, mutect2, varscan2
- BRINP2 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV64179297; called by muse, mutect2, varscan2
- BRPF1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100121355, COSV100121359; called by muse, mutect2, varscan2
- BTBD16 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as rs1186961546, COSV99585136; called by muse, mutect2, varscan2
- C10orf120 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV100271720; called by muse, mutect2, varscan2
- C12orf50 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.26); catalogued as rs536248523, COSV100072414; called by muse, mutect2, varscan2
- C17orf80 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99278347; called by muse, mutect2, varscan2
- C1QTNF9B | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221459808, COSV101158611; called by muse, mutect2, varscan2
- C22orf31 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV53310134; called by muse, mutect2, varscan2
- C3orf20 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.647); catalogued as COSV99514347; called by muse, mutect2, varscan2
- C8A | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV100776622, COSV63485847; called by muse, varscan2
- C8B | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64776698; called by muse, mutect2, varscan2
- C8B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as rs867837249, COSV64776574; called by muse, mutect2, varscan2
- C9orf135 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV101019905; called by muse, mutect2, varscan2
- CA5A | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs747262976, COSV59241572; called by muse, mutect2, varscan2
- CACNA1E | c.6266G>A p.R2089Q (on ENST00000367573 / NM_001205293.3; = p.R2046Q on NM_000721.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs779786799, COSV62385435; called by muse, mutect2, varscan2
- CACNA1I | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753483663, COSV100361103; called by muse, varscan2
- CACNA1S | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141395335, COSV62939642; called by muse, mutect2, varscan2
- CACNA1S | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100755222; called by muse, mutect2, varscan2
- CACNA1S | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62937806; called by muse, mutect2, varscan2
- CACNA2D1 | c.2626G>A p.G876R (on ENST00000356253 / NM_001366867.1; = p.G864R on NM_000722.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100667025; called by muse, mutect2, varscan2
- CACNG2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.448); catalogued as COSV100268329; called by muse, mutect2, varscan2
- CADM2 | c.626C>T p.S209F (on ENST00000407528 / NM_001167674.2; = p.S211F on NM_153184.4) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV67411544; called by muse, mutect2, varscan2
- CADPS2 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs1427094738, COSV100464853; called by muse, mutect2, varscan2
- CAMK1D | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.546); catalogued as COSV101123848; called by muse, mutect2, varscan2
- CAMK1D | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as COSV101123618, COSV101123849; called by muse, mutect2, varscan2
- CAMK2B | c.1674G>A p.A558= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as rs760353023, COSV99322959; called by muse, mutect2, varscan2
- CAMKV | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs190982523, COSV99615840; called by muse, mutect2, varscan2
- CASZ1 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1383045811, COSV100681903; called by muse, mutect2, varscan2
- CAT | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200680665, CM129767, COSV53811353; called by muse, mutect2, varscan2
- CATSPERE | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100835051, COSV100835290; called by muse, mutect2, varscan2
- CAV3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100373263; called by muse, mutect2, varscan2
- CBARP | c.101C>T p.P34L (on ENST00000382477; = p.P40L on NM_152769.3) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99289819; called by muse, mutect2, varscan2
- CBLL2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257570318, COSV60368932; called by muse, mutect2, varscan2
- CBY2 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs765265916, COSV60118825, COSV60119571; called by muse, mutect2, varscan2
- CCBE1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV67950290; called by muse, mutect2, varscan2
- CCDC114 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV100196945; called by muse, mutect2, varscan2
- CCDC141 | c.3834T>A p.D1278E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99836800; called by muse, mutect2
- CCDC141 | c.3832G>T p.D1278Y | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV55377281, COSV99837226; called by muse, mutect2
- CCDC141 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV55368838; called by muse, varscan2
- CCDC141 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs769268802, COSV55371354; called by muse, varscan2
- CCDC144A | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as rs750175196, COSV60701277; called by muse, mutect2, varscan2
- CCDC186 | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991130; called by muse, mutect2, varscan2
- CCDC189 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs769218304, COSV100079728; called by muse, mutect2, varscan2
- CCDC22 | c.975C>T p.V325= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100873219; called by muse, mutect2, varscan2
- CCDC40 | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100884298; called by muse, mutect2, varscan2
- CCDC50 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV101165338, COSV101165375; called by muse, mutect2
- CCDC68 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100491944, COSV61603701; called by muse, mutect2, varscan2
- CCDC89 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.502); catalogued as rs889180909, COSV57033835; called by muse, mutect2, varscan2
- CCT8L2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.946); catalogued as rs866460524, COSV63461772; called by muse, mutect2, varscan2
- CD101 | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99869971; called by muse, mutect2, varscan2
- CD14 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100117597; called by muse, mutect2, varscan2
- CD163L1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV100550480, COSV58010390; called by muse, mutect2, varscan2
- CD248 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV100256693; called by muse, mutect2, varscan2
- CD70 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99835626; called by muse, mutect2, varscan2
- CD96 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV99343313; called by muse, mutect2, varscan2
- CDC25A | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs1380293119, COSV100207611; called by muse, mutect2, varscan2
- CDC25C | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV60401478; called by muse, mutect2, varscan2
- CDC25C | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as COSV100086702; called by muse, mutect2, varscan2
- CDCA2 | c.1059T>G p.D353E | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100399025, COSV57944268; called by muse, mutect2, varscan2
- CDH10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570603, COSV52576617; called by muse, mutect2, varscan2
- CDH17 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs770933685, COSV99217786; called by muse, mutect2, varscan2
- CDH2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs17853634, COSV52276309; called by muse, mutect2, varscan2
- CDH2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV99297868; called by muse, mutect2, varscan2
- CDH23 | c.7663G>A p.A2555T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs757587541, COSV99822810; called by muse, varscan2
- CDH6 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs868021169, COSV54063594; called by muse, mutect2, varscan2
- CDK13 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 67/128 reads (52%) | catalogued as rs760503314, COSV99475854, COSV99475894; called by muse, mutect2, varscan2
- CDX4 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100999146, COSV65171737; called by muse, mutect2, varscan2
- CELSR2 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99604473; called by muse, mutect2, varscan2
- CEMIP | c.1299G>A p.W433* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as COSV54999021; called by muse, mutect2, varscan2
- CENPQ | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100225809, COSV100225823; called by muse, mutect2, varscan2
- CERS3 | c.701T>G p.V234G | Missense Mutation (SNP) | VAF 62/590 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs754294287, COSV99432459; called by muse, mutect2
- CETN1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1254036750, COSV100511317, COSV59121082; called by muse, mutect2, varscan2
- CFAP52 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV100235443; called by muse, mutect2, varscan2
- CFAP69 | c.1982T>C p.L661S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290343; called by muse, mutect2, varscan2
- CH25H | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV100897374; called by muse, mutect2, varscan2
- CHL1 | c.2165C>T p.A722V (on ENST00000397491 / NM_001253387.1; = p.A738V on NM_006614.4) | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99851861; called by muse, mutect2, varscan2
- CHRM4 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100708832; called by muse, mutect2, varscan2
- CHRNA9 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs554771896, COSV100039045; called by muse, mutect2, varscan2
- CHRNB1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99548454; called by muse, mutect2
- CHRNB1 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.759); catalogued as COSV100043694; called by muse, mutect2, varscan2
- CHRNB2 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1345782620, COSV100872650, COSV63808545; called by muse, mutect2, varscan2
- CHRND | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.803); catalogued as COSV51318610; called by muse, mutect2, varscan2
- CILP | c.1187-1G>A p.X396_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as rs776175304, COSV99973761; called by muse, mutect2
- CKMT1B | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100294628; called by muse, mutect2, varscan2
- CLEC4D | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs143281343; called by muse, mutect2, varscan2
- CLIP4 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs778977081, COSV100192228; called by muse, mutect2, varscan2
- CLNK | c.994T>A p.F332I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162738068, COSV99905599; called by muse, mutect2, varscan2
- CLVS2 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99253330; called by muse, mutect2, varscan2
- CMYA5 | c.5131G>A p.E1711K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV101484244; called by muse, mutect2, varscan2
- CMYA5 | c.8902G>A p.E2968K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101484245; called by muse, mutect2, varscan2
- CNGA2 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100323860; called by muse, mutect2, varscan2
- CNGA4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV101171840; called by muse, mutect2, varscan2
- CNGA4 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66007491; called by muse, mutect2, varscan2
- CNOT1 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55323995, COSV99800839; called by muse, mutect2, varscan2
- CNOT8 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99597246; called by muse, mutect2, varscan2
- CNTN5 | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.178); catalogued as rs1412882658, COSV99679659; called by muse, mutect2, varscan2
- CNTN6 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs370503610, COSV100611499; called by muse, mutect2, varscan2
- CNTNAP2 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV100669188; called by muse, mutect2, varscan2
- CNTNAP2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as rs765778701, COSV100669190; called by muse, mutect2, varscan2
- CNTNAP5 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70478708; called by muse, mutect2, varscan2
- COBL | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs771596666, COSV99473556; called by muse, mutect2, varscan2
- COL11A1 | c.4723G>A p.G1575R | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617738; called by muse, mutect2, varscan2
- COL11A1 | c.4168G>A p.G1390R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617739; called by muse, mutect2, varscan2
- COL14A1 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs200198894, COSV99920123; called by muse, mutect2, varscan2
- COL17A1 | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793263; called by muse, mutect2, varscan2
- COL17A1 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100793264; called by muse, mutect2, varscan2
- COL19A1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs142222422, COSV100506218, COSV100507039; called by muse, mutect2, varscan2
- COL1A1 | c.350C>G p.T117S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV99867852; called by muse, mutect2, varscan2
- COL20A1 | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs931102104, COSV100491055, COSV58919417; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL21A1 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769722166, COSV55163893, COSV99778638; called by muse, mutect2, varscan2
- COL21A1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55161262; called by muse, mutect2, varscan2
- COL22A1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100279813; called by muse, mutect2, varscan2
- COL3A1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483522; called by muse, mutect2, varscan2
- COL4A4 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61629701; called by muse, mutect2, varscan2
- COL6A3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV99800194; called by muse, mutect2, varscan2
- COL6A6 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs752996147, COSV62019642, COSV62023085; called by muse, mutect2, varscan2
- COL7A1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as rs1490442225, COSV99179001; called by muse, mutect2, varscan2
- COL9A1 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750991236, COSV100295246; called by muse, mutect2, varscan2
- COLEC12 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 43/118 reads (36%) | catalogued as COSV101232123; called by muse, mutect2, varscan2
- CORIN | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as rs866574072, COSV56690702; called by muse, mutect2, varscan2
- CP | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52835125, COSV99224334; called by muse, mutect2, varscan2
- CPA6 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99914274; called by muse, mutect2, varscan2
- CPED1 | c.2686C>T p.H896Y | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs751900906, COSV60005546; called by muse, mutect2, varscan2
- CPT1A | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs368052217; called by muse, mutect2, varscan2
- CPZ | c.820C>T p.P274S (on ENST00000360986 / NM_001014447.3; = p.P263S on NM_003652.3) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs753279964, COSV100249146, COSV59925169; called by muse, mutect2, varscan2
- CR2 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.145); catalogued as COSV100889682; called by muse, mutect2, varscan2
- CRB1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100959173; called by muse, mutect2, varscan2
- CRB1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV66329215; called by muse, mutect2, varscan2
- CRMP1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100272196; called by muse, mutect2, varscan2
- CRTAM | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs762410437, COSV99912182; called by muse, mutect2, varscan2
- CRYBG1 | c.4057G>A p.E1353K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV100954589; called by muse, mutect2, varscan2
- CSMD1 | c.8794C>T p.R2932W (on ENST00000520002; = p.R2931W on NM_033225.6) | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs773593396, COSV59319231; called by muse, mutect2, varscan2
- CSMD1 | c.7288G>A p.A2430T (on ENST00000520002; = p.A2429T on NM_033225.6) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1219098595, COSV100151854; called by muse, mutect2, varscan2
- CSMD2 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as COSV53897569, COSV53968476; called by muse, mutect2, varscan2
- CSMD3 | c.2065G>A p.E689K (on ENST00000297405 / NM_001363185.1; = p.E585K on NM_052900.3) | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1264242327, COSV52326121; called by muse, mutect2, varscan2
- CSPG4 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100413989; called by muse, mutect2, varscan2
- CSTF2T | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV58657380; called by muse, mutect2, varscan2
- CTCFL | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as rs1396058153, COSV54770986; called by muse, mutect2, varscan2
- CTNND1 | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1349348241, COSV100650218; called by muse, mutect2, varscan2
- CUL9 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99335782; called by muse, mutect2, varscan2
- CUZD1 | c.763T>A p.Y255N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100158919, COSV59025474; called by muse, mutect2, varscan2
- CUZD1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV100158921; called by muse, mutect2, varscan2
- CWC27 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101126558, COSV66888747; called by muse, mutect2, varscan2
- CX3CR1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV64195335; called by muse, mutect2, varscan2
- CYB5R4 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs758410641, COSV100859731; called by muse, mutect2, varscan2
- CYLD | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.999); catalogued as COSV100282652; called by muse, mutect2, varscan2
- CYP3A7 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 188/335 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100312771; called by muse, mutect2, varscan2
- CYP4F11 | c.150T>A p.C50* | Nonsense Mutation (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99931005; called by muse, mutect2, varscan2
- CYP4V2 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV101114945; called by muse, mutect2, varscan2
- CYP4V2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762287609, COSV101114946; called by muse, mutect2, varscan2
- CYP4Z1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs552332557, COSV61964845; called by muse, mutect2, varscan2
- DACH1 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100498949; called by muse, mutect2, varscan2
- DBT | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100923577, COSV64496468; called by muse, mutect2, varscan2
- DCAF12L2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100758744; called by muse, mutect2, varscan2
- DCAF12L2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV63584200; called by muse, mutect2, varscan2
- DCAF8L1 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1375113657, COSV101491516; called by muse, mutect2, varscan2
- DCC | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as COSV100502000; called by muse, mutect2, varscan2
- DCDC1 | c.4277G>A p.G1426E (on ENST00000597505 / NM_001367979.1; = p.G533E on NM_020869.3) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261185378, COSV100338583; called by muse, mutect2, varscan2
- DCUN1D2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 93/151 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100215294; called by muse, mutect2, varscan2
- DENND3 | c.3064C>T p.Q1022* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99371411; called by muse, mutect2, varscan2
- DENND5B | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171921; called by muse, mutect2, varscan2
- DEUP1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99977448; called by muse, mutect2, varscan2
- DGKB | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs772215117, COSV51772068; called by muse, mutect2, varscan2
- DGKK | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101053146; called by muse, mutect2, varscan2
- DLG5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs372736534; called by muse, mutect2, varscan2
- DLGAP3 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99333021; called by muse, mutect2, varscan2
- DMC1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53259073, COSV53261026; called by muse, mutect2, varscan2
- DMD | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876657781, COSV99924775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMP1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1363177923, COSV56822094; called by muse, mutect2, varscan2
- DMRTC2 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782072349, COSV54186118; called by muse, mutect2, varscan2
- DNAAF1 | c.1439A>T p.K480M | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV100533788; called by muse, mutect2, varscan2
- DNAH11 | c.5846G>A p.R1949Q | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs761919869, COSV100180092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.8306C>T p.A2769V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99769443; called by muse, mutect2, varscan2
- DNAH5 | c.8579A>T p.K2860I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99452380; called by muse, mutect2, varscan2
- DNAH5 | c.2692A>T p.S898C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99452382; called by muse, mutect2, varscan2
- DNAH7 | c.10717G>A p.E3573K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV100416296, COSV100416557; called by muse, mutect2, varscan2
- DNAH7 | c.7090C>T p.Q2364* | Nonsense Mutation (SNP) | VAF 42/84 reads (50%) | catalogued as rs866693631, COSV56760498; called by muse, mutect2, varscan2
- DNAH7 | c.6933G>A p.M2311I | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100416562; called by muse, mutect2, varscan2
- DNAH7 | c.3849G>A p.M1283I | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.697); catalogued as COSV100416566; called by muse, mutect2, varscan2
- DNAH7 | c.3534G>A p.W1178* | Nonsense Mutation (SNP) | VAF 42/91 reads (46%) | catalogued as rs1257750122, COSV100416568, COSV100417431; called by muse, mutect2, varscan2
- DNAH8 | c.2007G>A p.M669I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59471216; called by muse, mutect2, varscan2
- DNAH8 | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100546622; called by muse, mutect2, varscan2
- DNAH8 | c.4451C>T p.S1484F | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1309454133, COSV59479737; called by muse, mutect2, varscan2
- DNAH9 | c.3255G>A p.M1085I | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV99307197; called by muse, mutect2, varscan2
- DNAH9 | c.6739G>A p.V2247M | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as rs138590276; called by muse, mutect2, varscan2
- DNAH9 | c.6938A>G p.N2313S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99307200; called by muse, mutect2, varscan2
- DNAJA4 | c.148C>T p.Q50* (on ENST00000343789; = p.Q79* on NM_018602.3) | Nonsense Mutation (SNP) | VAF 43/292 reads (15%) | catalogued as COSV100655223; called by muse, varscan2
- DNAJC5B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV52536452; called by muse, mutect2, varscan2
- DNAJC5G | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs758282251, COSV56080095; called by muse, mutect2, varscan2
- DNASE1L3 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 23/41 reads (56%) | catalogued as COSV100568796; called by muse, mutect2, varscan2
- DNER | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100519723; called by muse, mutect2, varscan2
- DNHD1 | c.12985G>A p.D4329N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765728927, COSV99600668; called by muse, mutect2, varscan2
- DOCK11 | c.4628G>A p.G1543E | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs781516328, COSV99354384; called by muse, varscan2
- DOCK8 | c.4913C>T p.P1638L | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101210019; called by muse, mutect2, varscan2
- DOCK9 | c.1775C>T p.S592F (on ENST00000376460 / NM_001366676.2; = p.S593F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs373458404; called by muse, mutect2, varscan2
- DOP1A | c.6949C>T p.P2317S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99382590; called by muse, mutect2, varscan2
- DRC7 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV61054060; called by muse, mutect2, varscan2
- DRD2 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); catalogued as COSV100669937; called by muse, mutect2, varscan2
- DRP2 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871999; called by muse, mutect2, varscan2
- DSC1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99938007; called by muse, mutect2, varscan2
- DTX3 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.021); catalogued as COSV99678184; called by muse, mutect2
- DUOX1 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100368277; called by muse, mutect2, varscan2
- DUSP9 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781910246, COSV100720146; called by muse, mutect2, varscan2
- DYNC2H1 | c.11941C>T p.R3981C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.86); catalogued as rs377295698; called by muse, mutect2, varscan2
- DYRK4 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV99157352; called by muse, mutect2, varscan2
- ECM2 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 111/136 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1260276086, COSV100755950; called by muse, mutect2, varscan2
- EDAR | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV99304018; called by muse, mutect2, varscan2
- EFL1 | c.1686C>A p.N562K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99187979; called by muse, mutect2, varscan2
- EHBP1 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99861484; called by muse, mutect2, varscan2
- EIF5 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs144699320, COSV99384873; called by muse, mutect2, varscan2
- ELAVL3 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs763101515, COSV100820826; called by muse, mutect2, varscan2
- ELF5 | c.367C>T p.Q123* (on ENST00000312319 / NM_198381.2; = p.Q113* on NM_001422.4) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1164869420, COSV99141247; called by muse, mutect2
- ELP4 | c.949C>A p.R317S (on ENST00000350638; = p.R316S on NM_019040.5) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs764805051, COSV100635078, COSV100635774; called by muse, mutect2, varscan2
- EMILIN3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV100182726; called by muse, mutect2, varscan2
- ENAM | c.2838A>C p.R946S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101253271; called by muse, mutect2, varscan2
- ENG | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV100785331; called by muse, mutect2, varscan2
- ENPP4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs1262614085, COSV100320409, COSV58088422; called by muse, mutect2, varscan2
- ENPP7 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.021); catalogued as rs1555823960, COSV100093307, COSV60385893; called by muse, mutect2, varscan2
- ENTHD1 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV57326390; called by muse, mutect2, varscan2
- EPB41L4A | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99813824; called by muse, mutect2, varscan2
- EPB42 | c.388C>T p.L130F (on ENST00000441366 / NM_001114134.2; = p.L160F on NM_000119.3) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.564); catalogued as COSV100282080; called by muse, mutect2, varscan2
- EPC2 | c.1700C>T p.T567I | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.969); catalogued as COSV99309554, COSV99309993; called by muse, mutect2, varscan2
- EPHA6 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV101064793; called by muse, mutect2, varscan2
- EPHA8 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs562198376, COSV51262872; called by muse, mutect2, varscan2
- EPHX2 | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV100994726; called by muse, mutect2, varscan2
- EPS8L2 | c.803G>A p.W268* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs1308329158, COSV100585654; called by muse, mutect2, varscan2
- ERAP2 | c.1506T>C p.S502= | Splice Region (SNP) | VAF 34/89 reads (38%) | catalogued as rs984490546, COSV101163819; called by muse, mutect2, varscan2
- ERAP2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs201095797, COSV65941444; called by muse, mutect2, varscan2
- ERC2 | c.300T>A p.S100R | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99887706; called by muse, mutect2, varscan2
- ERC2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs780679678, COSV55628775; called by muse, mutect2, varscan2
- ERCC6L | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100559213; called by muse, mutect2, varscan2
- ERICH3 | c.3332C>T p.A1111V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100445141; called by muse, mutect2, varscan2
- ERICH3 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV100445538, COSV58615805; called by muse, varscan2
- ESF1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs752291941, COSV99176466; called by muse, mutect2, varscan2
- ESF1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV99176282; called by muse, mutect2, varscan2
- ETV3L | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV101485608; called by muse, mutect2, varscan2
- EXPH5 | c.4307G>A p.G1436E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs779315623, COSV56200707; called by muse, mutect2, varscan2
- EXPH5 | c.4190C>T p.S1397L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs757762764, COSV56207614, COSV99761991; called by muse, mutect2, varscan2
- EYA1 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100380014; called by muse, mutect2, varscan2
- EYA4 | c.1254G>A p.M418I (on ENST00000531901 / NM_001301013.1; = p.M412I on NM_004100.5) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV62046235; called by muse, mutect2, varscan2
- EYS | c.949A>C p.T317P | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100676924; called by muse, mutect2, varscan2
- EYS | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60983669; called by muse, mutect2, varscan2
- EZHIP | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.865); catalogued as COSV100539816, COSV57957857; called by muse, mutect2, varscan2
- F8 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM082640, COSV100811718; called by muse, mutect2, varscan2
- FAAH2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 79/208 reads (38%) | catalogued as rs1394464687, COSV66506732; called by muse, mutect2, varscan2
- FADS2 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.604); catalogued as COSV99608978; called by muse, mutect2, varscan2
- FAM120C | c.2353C>T p.H785Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV100070332; called by muse, mutect2, varscan2
- FAM133A | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100220562; called by muse, mutect2, varscan2
- FAM155A | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV101029557; called by muse, mutect2, varscan2
- FAM171A1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV65316129; called by muse, mutect2, varscan2
- FAM209A | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99711635; called by muse, mutect2, varscan2
- FAM209B | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100990998, COSV64915329; called by muse, mutect2, varscan2
- FAM217A | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99212782; called by muse, mutect2, varscan2
- FAM3A | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs782658047, COSV100453683; called by muse, mutect2, varscan2
- FAM47C | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV100792850; called by muse, mutect2, varscan2
- FAM53C | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as COSV99524495; called by muse, mutect2, varscan2
- FAM71A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 74/109 reads (68%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV54235658, COSV99674787; called by muse, mutect2, varscan2
- FAM78B | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1222410193, COSV100597723; called by muse, mutect2, varscan2
- FAM83A | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV99414463; called by muse, mutect2, varscan2
- FAM83C | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100981637; called by muse, mutect2, varscan2
- FAM83F | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866126398, COSV61000914; called by muse, mutect2, varscan2
- FAM90A1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.655); catalogued as rs750289614, COSV56715116; called by muse, mutect2, varscan2
- FAT3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99968647; called by muse, mutect2, varscan2
- FAT4 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67897326; called by muse, mutect2, varscan2
- FAT4 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327750778, COSV101272547; called by muse, mutect2, varscan2
- FAT4 | c.8575G>A p.D2859N | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs369900313; called by muse, mutect2, varscan2
- FAT4 | c.13697C>T p.P4566L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV58674970; called by muse, mutect2, varscan2
- FBN1 | c.5732C>T p.S1911F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57332692; called by muse, mutect2, varscan2
- FBN2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs962522833, COSV99329521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99329524; called by muse, mutect2, varscan2
- FBXL7 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as rs1236967249, COSV100310424; called by muse, mutect2, varscan2
- FBXO38 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99693776; called by muse, mutect2, varscan2
- FBXO9 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764924520, COSV99762588; called by muse, varscan2
- FBXW12 | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99601754; called by muse, mutect2, varscan2
- FCAR | c.616T>G p.F206V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV100629146; called by muse, mutect2, varscan2
- FCER1A | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100929292; called by muse, mutect2, varscan2
- FCRL1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV63827667; called by muse, mutect2, varscan2
- FCRL5 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 78/119 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs762961843, COSV62517656; called by muse, mutect2, varscan2
- FGD2 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758759895, COSV51466401; called by muse, mutect2, varscan2
- FGF13 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.905); catalogued as COSV65432774; called by muse, mutect2, varscan2
- FGF23 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.912); catalogued as COSV52975503; called by muse, mutect2, varscan2
- FGF5 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV100428001; called by muse, mutect2, varscan2
- FGF6 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99960360; called by muse, mutect2, varscan2
- FGF6 | c.175T>A p.S59T | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV99960362; called by muse, mutect2, varscan2
- FLG | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 231/894 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100911917; called by muse, mutect2, varscan2
- FLRT2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV58138141; called by muse, mutect2, varscan2
- FMNL2 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99980339; called by muse, mutect2, varscan2
- FMO3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868604370, COSV63007410; called by muse, mutect2, varscan2
- FN1 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs201863538, COSV100118473, COSV60566745; called by muse, mutect2, varscan2
- FRAS1 | c.8650G>A p.E2884K | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99354569; called by muse, mutect2, varscan2
- FSCB | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV61219638; called by muse, mutect2, varscan2
- FSIP2 | c.17688G>A p.M5896I | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs1433987923, COSV100555850; called by muse, mutect2, varscan2
- FTSJ1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99191441; called by muse, mutect2, varscan2
- FURIN | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99184753; called by muse, mutect2, varscan2
- FYB1 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs773327830, COSV60946448; called by muse, mutect2, varscan2
- GABRA4 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99974446; called by muse, mutect2, varscan2
- GABRG1 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV54956464; called by muse, mutect2, varscan2
- GABRG2 | c.1094C>T p.S365L (on ENST00000361925 / NM_001375343.1; = p.S325L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62717482; called by muse, mutect2, varscan2
- GALNT5 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1289611699, COSV52039154; called by muse, mutect2, varscan2
- GALNT7 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99397650; called by muse, mutect2, varscan2
- GAREM1 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as rs755005444, COSV52508586; called by muse, mutect2, varscan2
- GCM2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV65275767; called by muse, mutect2
- GCNT3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV68532082; called by muse, mutect2, varscan2
- GCSAML | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100826009; called by muse, mutect2, varscan2
- GCSAML | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1162841912, COSV100826011; called by muse, mutect2, varscan2
- GDF10 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs782455115; called by muse, mutect2, varscan2
- GFRAL | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100474737, COSV61228786; called by muse, mutect2, varscan2
- GGT5 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV99571764; called by muse, mutect2, varscan2
- GHR | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.549); catalogued as COSV100051599; called by muse, mutect2, varscan2
- GIMAP2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.347); catalogued as COSV56235453; called by muse, mutect2, varscan2
- GIN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs782667095, COSV67535928; called by muse, mutect2, varscan2
- GJA5 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99605739; called by muse, varscan2
- GLI3 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101229966; called by muse, mutect2, varscan2
- GLI3 | c.366C>T p.Y122= | Splice Region (SNP) | VAF 14/54 reads (26%) | catalogued as rs1366557334, HM972180, COSV67886204; called by muse, mutect2, varscan2
- GLRA3 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs768235434, COSV56864006; called by muse, mutect2, varscan2
- GLYATL2 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99780477; called by muse, mutect2, varscan2
- GLYATL2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); catalogued as COSV99780481; called by muse, mutect2, varscan2
- GLYCTK | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1348883081, COSV99980882; called by muse, mutect2, varscan2
- GNPDA2 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99776999; called by muse, mutect2, varscan2
- GPBP1L1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV99322608; called by muse, mutect2, varscan2
- GPC3 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs1286338239, COSV100893379; called by muse, mutect2, varscan2
- GPKOW | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99332757; called by muse, mutect2, varscan2
- GPR12 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101198009; called by muse, mutect2, varscan2
- GPR139 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58503758; called by muse, mutect2, varscan2
- GPR19 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60124306; called by muse, mutect2, varscan2
- GPR26 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382331412, COSV99501028; called by muse, mutect2, varscan2
- GPRC6A | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758808114, COSV100114620; called by muse, mutect2, varscan2
- GRIA1 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99601370; called by muse, mutect2, varscan2
- GRIA2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs142538282, COSV52402874; called by muse, mutect2, varscan2
- GRID2 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56191319; called by muse, mutect2, varscan2
- GRIK4 | c.512-1G>A p.X171_splice | Splice Site (SNP) | VAF 25/78 reads (32%) | catalogued as COSV101483679; called by muse, mutect2, varscan2
- GRIN2A | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58021069; called by muse, mutect2, varscan2
- GRIP1 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99670412; called by muse, mutect2, varscan2
- GRM8 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV100284938; called by muse, mutect2, varscan2
- GSTM5 | c.456+1G>A p.X152_splice | Splice Site (SNP) | VAF 30/83 reads (36%) | catalogued as rs371246652; called by muse, mutect2, varscan2
- GTDC1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866716071, COSV99599318, COSV99601355; called by muse, mutect2, varscan2
- GTF3C2 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as COSV99273114; called by muse, mutect2, varscan2
- HACE1 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1324802233, COSV53503194; called by muse, mutect2, varscan2
- HCLS1 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV100100975; called by muse, mutect2, varscan2
- HCN3 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.013); catalogued as rs1426900894, COSV100712976; called by muse, mutect2, varscan2
- HCRTR2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100904510, COSV63793838; called by muse, varscan2
- HDC | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV99984226; called by muse, mutect2, varscan2
- HEATR3 | c.2030G>A p.R677K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV99590049; called by muse, mutect2, varscan2
- HEATR5A | c.4432C>T p.P1478S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV66339321; called by muse, mutect2, varscan2
- HEG1 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100230808; called by muse, mutect2
- HHIP | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56839939, COSV56840502; called by muse, mutect2, varscan2
- HIP1 | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 106/437 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782712426, COSV61190764; called by muse, mutect2, varscan2
- HIPK3 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100305959; called by muse, mutect2, varscan2
- HIPK3 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100305961; called by muse, mutect2, varscan2
- HK1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100067447; called by muse, mutect2, varscan2
- HK3 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.259); catalogued as rs1171894965, COSV99459045; called by muse, mutect2, varscan2
- HLCS | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140014588; called by muse, mutect2, varscan2
- HNF4G | c.61G>A p.G21R (on ENST00000354370 / NM_001330561.2; = p.G68R on NM_004133.5) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584840; called by muse, mutect2, varscan2
- HNRNPH2 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV99516509; called by muse, mutect2, varscan2
- HPR | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1278404831, COSV99930991; called by muse, mutect2, varscan2
- HRNR | c.5663G>A p.G1888E | Missense Mutation (SNP) | VAF 202/2063 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs765912905, COSV64254648; called by muse, mutect2, varscan2
- HS3ST2 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99758421; called by muse, mutect2, varscan2
- HS3ST4 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58805054, COSV58820680; called by muse, mutect2, varscan2
- HS3ST5 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV100451216; called by muse, mutect2, varscan2
- HSD3B2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as COSV101027535; called by muse, mutect2, varscan2
- HSPG2 | c.6148C>T p.P2050S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101020969; called by muse, mutect2, varscan2
- HTR3A | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100248542; called by muse, mutect2, varscan2
- HTR6 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as COSV99230364; called by muse, mutect2, varscan2
- HUWE1 | c.13000C>T p.R4334C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99470919; called by muse, mutect2, varscan2
- HYOU1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV101345645; called by muse, mutect2, varscan2
- IFI16 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1361119576, COSV99857960; called by muse, mutect2, varscan2
- IFI30 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717624; called by muse, mutect2
- IFIH1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99718777; called by muse, mutect2, varscan2
- IGFALS | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51908434; called by muse, mutect2, varscan2
- IGKJ5 | c.3G>A p.*1= | Missense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs368660113; called by muse, mutect2, varscan2
- IGSF5 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV66029331; called by muse, mutect2, varscan2
- IGSF8 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100081774; called by muse, mutect2, varscan2
- IL15RA | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV101181859; called by muse, mutect2, varscan2
- IL18R1 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99295376; called by muse, mutect2, varscan2
- IL1RAPL1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100149209; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61147293; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV61143968, COSV61172298; called by muse, mutect2, varscan2
- IL1RL2 | c.258A>C p.E86D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99960974; called by muse, mutect2, varscan2
- IL5RA | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV56524800; called by muse, mutect2, varscan2
- INTS6L | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV66085682; called by muse, mutect2, varscan2
- INTS6L | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100878222; called by muse, mutect2
- IPO11 | c.1077T>G p.Y359* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV100321238; called by muse, mutect2, varscan2
- IQCN | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV101148888; called by muse, mutect2, varscan2
- IRS4 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100929651; called by muse, mutect2, varscan2
- ISM2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs748323494, COSV99376791; called by muse, mutect2, varscan2
- ITFG1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141409020; called by muse, mutect2, varscan2
- ITGA11 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100241986; called by muse, mutect2
- JHY | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs746470145, COSV99913176; called by muse, mutect2, varscan2
- JMJD1C | c.618T>A p.F206L | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.475); catalogued as COSV101232450; called by muse, mutect2, varscan2
- KAT8 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54897934, COSV99571706; called by muse, mutect2, varscan2
- KATNA1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100167930; called by muse, mutect2
- KCNB1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100870559; called by muse, mutect2, varscan2
- KCNB2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV73049978; called by muse, mutect2, varscan2
- KCNH2 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100060675; called by muse, mutect2, varscan2
- KCNH8 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100110705, COSV60475687; called by muse, mutect2, varscan2
- KCNJ14 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as rs1322321591, COSV100287302; called by muse, mutect2
- KCNJ3 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as COSV54540166, COSV99716248; called by muse, mutect2, varscan2
- KCNQ3 | c.2170G>A p.G724R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV101195827; called by muse, mutect2, varscan2
- KCNQ5 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59648044, COSV59671953; called by muse, mutect2, varscan2
- KCNU1 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); catalogued as COSV101299363; called by muse, mutect2, varscan2
- KCTD16 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV101568850; called by muse, mutect2, varscan2
- KCTD3 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV99379580; called by muse, mutect2, varscan2
- KDF1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753712013, COSV57671911; called by muse, mutect2, varscan2
- KIAA0825 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs934109207, COSV56950262; called by muse, mutect2, varscan2
- KIAA1210 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as COSV101274335; called by muse, mutect2, varscan2
- KIAA1217 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV100286232; called by muse, mutect2, varscan2
- KIF1C | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100297269; called by muse, mutect2, varscan2
- KIF21B | c.3584C>T p.T1195I | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as COSV100144889; called by muse, mutect2, varscan2
- KIF21B | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100144896; called by muse, mutect2, varscan2
- KIF2B | c.1999C>T p.H667Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV99275877; called by muse, mutect2, varscan2
- KIF4A | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs776581139, COSV100978679; called by muse, mutect2, varscan2
- KITLG | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99933485; called by muse, mutect2, varscan2
- KLHL13 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99452207; called by muse, mutect2, varscan2
- KLHL13 | c.83T>A p.L28H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99452209; called by muse, mutect2, varscan2
- KLHL31 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV100911830; called by muse, mutect2, varscan2
- KLHL32 | c.1414-1G>A p.X472_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100987435; called by muse, mutect2, varscan2
- KPNA2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs781870365, COSV100388843; called by muse, mutect2, varscan2
- KRBOX4 | c.337G>A p.E113K (on ENST00000344302 / NM_001129898.2; = p.E108K on NM_017776.2) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.956); catalogued as COSV99994339; called by muse, mutect2, varscan2
- KRT16 | c.1281-1G>A p.X427_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as rs112929229, COSV100053006; called by muse, mutect2, varscan2
- KRT20 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.26); catalogued as rs778445618, COSV51425307; called by muse, mutect2, varscan2
- KRT33B | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV52442646; called by muse, mutect2, varscan2
- KRT5 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99358180; called by muse, mutect2, varscan2
- KRT83 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531808; called by muse, mutect2, varscan2
- KRT83 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs1225549724, COSV53343074; called by muse, mutect2, varscan2
- KRT83 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs757428966, COSV53339988; called by muse, mutect2, varscan2
- KRTAP9-2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs759475584, COSV100893218; called by muse, mutect2, varscan2
- KRTAP9-4 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1278655778, COSV100484925; called by muse, mutect2, varscan2
- KSR1 | c.787C>T p.R263C (on ENST00000644974 / NM_001367810.1; = p.R126C on NM_014238.2) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs757739661, COSV52029108, COSV99259999; called by muse, mutect2, varscan2
- L1CAM | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100649386; called by muse, mutect2, varscan2
- L1CAM | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100649387; called by muse, mutect2, varscan2
- L1CAM | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.184); catalogued as COSV100649388; called by muse, mutect2, varscan2
- L1CAM | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV100649391; called by muse, mutect2, varscan2
- L1TD1 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV100776613; called by muse, mutect2, varscan2
- L3MBTL1 | c.1819C>T p.P607S (on ENST00000418998 / NM_001377303.1; = p.P517S on NM_015478.7) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100917032; called by muse, mutect2, varscan2
- L3MBTL3 | c.1147A>G p.K383E | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV100696318; called by muse, mutect2, varscan2
- LAG3 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99179976; called by muse, mutect2, varscan2
- LAMC2 | c.79+1G>A p.X27_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as rs1409174019, COSV99917021; called by muse, varscan2
- LARP1B | c.1524G>A p.K508= | Splice Region (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99218686; called by muse, mutect2, varscan2
- LARP1B | c.1685-1G>A p.X562_splice | Splice Site (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99218688; called by muse, mutect2, varscan2
- LCT | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.41); catalogued as COSV99930098; called by muse, mutect2, varscan2
- LCTL | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100328848; called by muse, mutect2, varscan2
- LDHC | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99772630; called by muse, mutect2, varscan2
- LEPR | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60757367; called by muse, mutect2, varscan2
- LEPR | c.3392G>A p.G1131E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.703); catalogued as COSV100848166, COSV100848233; called by muse, mutect2, varscan2
- LGR6 | c.452C>T p.S151F (on ENST00000367278 / NM_001017403.1; = p.S99F on NM_021636.3) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs867671554, COSV99707579; called by muse, mutect2, varscan2
- LILRB1 | c.1286G>A p.G429E (on ENST00000427581; = p.G393E on NM_006669.6) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100207636; called by muse, varscan2
- LILRB2 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.112); catalogued as rs778059559, COSV100079394; called by muse, mutect2, varscan2
- LIMK2 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs1046954174, COSV59183733; called by muse, mutect2, varscan2
- LIN28B | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100559002; called by muse, mutect2, varscan2
- LIN28B | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV61495518; called by muse, mutect2, varscan2
- LINGO1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487995400, COSV100796466; called by muse, mutect2, varscan2
- LINS1 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 27/581 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1250553618, COSV59078892; called by muse, mutect2
- LIPG | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV99724630; called by muse, mutect2
- LLGL2 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs963325779, COSV51392802; called by muse, mutect2, varscan2
- LMBRD1 | c.1129C>T p.L377F (on ENST00000649011; = p.L355F on NM_018368.4) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100992658; called by muse, mutect2, varscan2
- LPA | c.3698C>T p.P1233L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1201280250, COSV100307622; called by muse, mutect2, varscan2
- LPP | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1322222495, COSV100447985; called by muse, mutect2, varscan2
- LRFN3 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771200514, COSV99873509; called by muse, varscan2
- LRFN5 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984925; called by muse, mutect2, varscan2
- LRIG1 | c.1902G>T p.K634N | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459575291, COSV99834138; called by muse, mutect2, varscan2
- LRP10 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as rs143726473; called by muse, mutect2, varscan2
- LRP1B | c.4895G>A p.R1632Q | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777763232, COSV67191741; called by muse, mutect2, varscan2
- LRP1B | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs1187018129, COSV101259053; called by muse, mutect2, varscan2
- LRP2 | c.12077G>A p.G4026E | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789677; called by muse, mutect2, varscan2
- LRP2 | c.7178C>T p.A2393V | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV99789678; called by muse, mutect2, varscan2
- LRP4 | c.5509C>T p.L1837F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.969); catalogued as rs540240854, COSV101066777; called by muse, mutect2, varscan2
- LRP5 | c.4579C>T p.P1527S | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs757890963, COSV99592444; called by muse, mutect2, varscan2
- LRRC43 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs774218011, COSV60289398; called by muse, mutect2, varscan2
- LRRC43 | c.663-1G>A p.X221_splice | Splice Site (SNP) | VAF 46/146 reads (32%) | catalogued as rs1386655358, COSV100336867; called by muse, mutect2, varscan2
- LRRC49 | c.886A>C p.M296L | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99537918; called by muse, mutect2, varscan2
- LRRC4C | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99539113; called by muse, mutect2, varscan2
- LRRC7 | c.4307G>A p.G1436E (on ENST00000651989 / NM_001370785.2; = p.G1356E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs267598708, COSV50646682; called by muse, mutect2, varscan2
- LRRIQ1 | c.5008C>T p.Q1670* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV101280657; called by muse, mutect2, varscan2
- LRRIQ3 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 51/128 reads (40%) | catalogued as COSV100599107; called by muse, varscan2
- LRRIQ3 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV63041391; called by muse, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LRRK1 | c.4664G>A p.G1555E | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV99441984; called by muse, mutect2
- LRRTM4 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV69140127; called by muse, mutect2, varscan2
- LUZP2 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV100420811; called by muse, mutect2, varscan2
- LVRN | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.038); catalogued as COSV100773603; called by muse, mutect2, varscan2
- MACC1 | c.2354G>A p.W785* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as rs201028666; called by muse, mutect2, varscan2
- MADD | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs375520658; called by muse, mutect2, varscan2
- MAGEA11 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100290617; called by muse, mutect2, varscan2
- MAGEA8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs782267175, COSV54064067; called by muse, mutect2, varscan2
- MAGED1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.456); catalogued as rs782539728, COSV58516917; called by muse, mutect2
- MAGEL2 | c.2186G>A p.R729K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); catalogued as COSV100046121; called by muse, mutect2, varscan2
- MAP1A | c.4276G>A p.D1426N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100289009; called by muse, mutect2, varscan2
- MAP3K21 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1322245837, COSV100786137; called by muse, mutect2, varscan2
- MAP4K4 | c.3550C>T p.R1184* (on ENST00000347699 / NM_001242559.2; = p.R1110* on NM_004834.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs1188785212, COSV56327274; called by muse, mutect2, varscan2
- MARCHF10 | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 35/105 reads (33%) | catalogued as COSV100248442; called by muse, mutect2, varscan2
- MARCHF4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99814667; called by muse, mutect2, varscan2
- MAST4 | c.3164C>T p.S1055F (on ENST00000403625 / NM_001164664.2; = p.S866F on NM_015183.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs867630014, COSV99845195; called by muse, mutect2, varscan2
- MBTPS2 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.7); PolyPhen possibly damaging (0.485); catalogued as COSV100810824; called by muse, mutect2, varscan2
- MC5R | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 162/373 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as rs1398224114, COSV100229116; called by muse, mutect2, varscan2
- MCF2 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100644975; called by muse, mutect2, varscan2
- MCF2 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1216354437, COSV58481767; called by muse, mutect2, varscan2
- MCM4 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs201708189; called by muse, mutect2, varscan2
- MCRS1 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99235577; called by muse, varscan2
- MDC1 | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100903009; called by muse, mutect2, varscan2
- MED30 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99816110; called by muse, mutect2, varscan2
- MEGF10 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99174742, COSV99175250; called by muse, mutect2, varscan2
- MEP1A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV100042959; called by muse, mutect2, varscan2
- MEPE | c.535A>C p.I179L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100734975; called by muse, mutect2, varscan2
- METTL7A | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs1239733714, COSV100153707; called by muse, mutect2, varscan2
- MFSD4A | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100901664; called by muse, mutect2, varscan2
- MGAM | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV72075822; called by muse, mutect2, varscan2
- MGAM | c.4301C>T p.P1434L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV101527360; called by muse, mutect2
- MGAT1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | PolyPhen probably damaging (1); catalogued as COSV57134505; called by muse, varscan2
- MKI67 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64076581; called by muse, mutect2, varscan2
- MKX | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101008845; called by muse, mutect2, varscan2
- MLEC | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99949727; called by muse, mutect2, varscan2
- MME | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100852488; called by muse, mutect2, varscan2
- MMP10 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.479); catalogued as COSV99666694; called by muse, mutect2, varscan2
- MMP2 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0.169); catalogued as COSV99528083; called by muse, mutect2, varscan2
- MMRN1 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53339383; called by muse, mutect2, varscan2
- MNDA | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100933412; called by muse, mutect2, varscan2
- MORC1 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as COSV99227184; called by muse, mutect2, varscan2
- MOV10L1 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV99434630; called by muse, mutect2, varscan2
- MOXD1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.53); catalogued as rs905169577, COSV100381256, COSV100381788; called by muse, mutect2, varscan2
- MPDZ | c.3118G>A p.G1040S | Missense Mutation (SNP) | VAF 113/145 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100057276; called by muse, mutect2, varscan2
- MPEG1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs377026755; called by muse, mutect2, varscan2
- MPP6 | c.651G>A p.Q217= | Splice Region (SNP) | VAF 22/39 reads (56%) | catalogued as COSV99757706, COSV99757747; called by muse, mutect2, varscan2
- MROH7 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs1233105795, COSV59873899; called by muse, mutect2, varscan2
- MROH9 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.095); catalogued as rs754335398, COSV63010549, COSV63011949; called by muse, mutect2, varscan2
- MRPS35 | c.569T>C p.L190S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99317595; called by muse, mutect2, varscan2
- MS4A1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1313395216, COSV100619394; called by muse, mutect2, varscan2
- MS4A10 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382383; called by muse, mutect2, varscan2
- MS4A14 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100280639, COSV55733242; called by muse, mutect2, varscan2
- MTMR7 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs370669270; called by muse, mutect2, varscan2
- MTUS2 | c.3113G>A p.R1038K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs773465650, COSV101462311; called by muse, mutect2
- MUC16 | c.39809G>A p.G13270E | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs748605201, COSV66690219; called by muse, mutect2, varscan2
- MUC16 | c.36913C>T p.R12305C | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as rs367821186; called by muse, mutect2, varscan2
- MUC16 | c.33545C>T p.S11182L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV67461440; called by muse, mutect2, varscan2
- MUC16 | c.30902C>T p.S10301L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV101200645; called by muse, mutect2, varscan2
- MUC16 | c.28037C>T p.S9346F | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.534); catalogued as rs574413975, COSV101200646; called by muse, mutect2, varscan2
- MUC16 | c.27191G>A p.R9064K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.028); catalogued as COSV101200647; called by muse, mutect2, varscan2
- MUC16 | c.26297C>T p.S8766F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV67453202; called by muse, mutect2, varscan2
- MUC16 | c.18607G>A p.D6203N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.065); catalogued as COSV101198459; called by muse, mutect2, varscan2
- MUC16 | c.17852C>T p.P5951L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1329378131, COSV101200648; called by muse, mutect2, varscan2
- MUC16 | c.15701C>T p.S5234F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV67445111; called by muse, mutect2
- MUC16 | c.15635C>T p.S5212F | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67492272; called by muse, mutect2, varscan2
- MUC16 | c.8983C>T p.P2995S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67477601; called by muse, mutect2, varscan2
- MUC16 | c.5582C>T p.T1861I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101200650; called by muse, mutect2, varscan2
- MUC16 | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as rs769830116, COSV67454358; called by muse, mutect2, varscan2
- MUC16 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101200651; called by muse, mutect2, varscan2
- MUC17 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 137/528 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100074449, COSV60283660; called by muse, mutect2, varscan2
- MUC3A | c.7895C>T p.P2632L | Missense Mutation (SNP) | VAF 76/489 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs564248922, COSV100115088; called by muse, mutect2, varscan2
- MUC5B | c.13015G>A p.E4339K | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV101500611; called by muse, mutect2, varscan2
- MYCBP2 | c.9085C>T p.P3029S (on ENST00000357337; = p.P3067S on NM_015057.5) | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs368061872; called by muse, mutect2, varscan2
- MYCBP2 | c.8479C>T p.P2827S (on ENST00000357337; = p.P2865S on NM_015057.5) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.979); catalogued as rs1170240057, COSV100631219; called by muse, mutect2, varscan2
- MYH13 | c.3539G>A p.R1180K | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV52822718; called by muse, mutect2, varscan2
- MYH4 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1313161665, COSV55115455; called by muse, mutect2, varscan2
- MYH6 | c.2869G>A p.D957N | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100676847; called by muse, mutect2, varscan2
- MYH8 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101238578; called by muse, mutect2, varscan2
- MYO15A | c.10205C>T p.A3402V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99233838; called by muse, mutect2, varscan2
- MYO18B | c.4409C>T p.A1470V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as COSV100124532; called by muse, mutect2, varscan2
- MYO1F | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV57791484; called by muse, mutect2, varscan2
- MYO1F | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV100596930; called by muse, mutect2, varscan2
- MYO1F | c.90A>T p.E30D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as rs939649517, COSV100596931; called by muse, mutect2, varscan2
- MYO6 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100889392; called by muse, mutect2, varscan2
- MYO7B | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268227, COSV101268333; called by muse, mutect2, varscan2
- N4BP3 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs767083843, COSV99200764; called by muse, varscan2
- NALCN | c.878T>A p.F293Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV99216788; called by muse, mutect2, varscan2
- NCAM1 | c.2108C>T p.S703L (on ENST00000316851 / NM_181351.5; = p.S693L on NM_000615.7) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs782806643, COSV100378269; called by muse, mutect2, varscan2
- NCDN | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs1028945097, COSV100357578; called by mutect2, varscan2
- NCKAP5 | c.3089C>T p.T1030I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV58475204; called by muse, mutect2, varscan2
- NCMAP | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs766589597, COSV100980305; called by muse, mutect2, varscan2
- NCOR2 | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100657716; called by muse, mutect2, varscan2
- NDUFA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV101007081; called by muse, mutect2, varscan2
- NEBL | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs758877499, COSV65805832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK11 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV100797820; called by muse, mutect2, varscan2
- NEK5 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 50/89 reads (56%) | catalogued as rs762770734, COSV100839276; called by muse, mutect2, varscan2
- NEU4 | c.1402C>T p.P468S (on ENST00000391969 / NM_001167602.3; = p.P480S on NM_080741.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs773204147, COSV100372160; called by muse, mutect2, varscan2
- NEURL4 | c.3363C>T p.G1121= | Splice Region (SNP) | VAF 72/168 reads (43%) | catalogued as COSV100223186; called by muse, mutect2, varscan2
- NEURL4 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs746562526, COSV100224510; called by muse, varscan2
- NEXMIF | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1472519537, COSV50024924; called by muse, mutect2, varscan2
- NFASC | c.2764G>A p.E922K (on ENST00000339876 / NM_001378329.1; = p.E1025K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as COSV100365063; called by muse, mutect2, varscan2
- NFATC3 | c.1846C>T p.H616Y | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60480162; called by muse, mutect2, varscan2
- NIBAN1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV100836506, COSV104422900; called by muse, mutect2, varscan2
- NLRP1 | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757725753, COSV52571892; called by muse, mutect2, varscan2
- NLRP1 | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); catalogued as rs1446162413, COSV99335053; called by muse, mutect2, varscan2
- NLRP11 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV64086493; called by muse, mutect2
- NLRP13 | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as COSV100738397; called by muse, mutect2, varscan2
- NLRP14 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs779428614, COSV100205280; called by muse, mutect2, varscan2
- NLRP2 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1164249967, COSV54755524; called by muse, mutect2
- NLRP4 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs868450451, COSV56715942; called by muse, mutect2, varscan2
- NLRP5 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs780828462, COSV66763274, COSV66766342; called by muse, mutect2, varscan2
- NLRP8 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52584772; called by muse, mutect2, varscan2
- NLRP9 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs752258952, COSV60461708; called by muse, mutect2, varscan2
- NMBR | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs777023719, COSV57803369; called by muse, mutect2, varscan2
- NOBOX | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99779593; called by muse, mutect2, varscan2
- NOS1 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1029861467, COSV100500011; called by muse, mutect2
- NOS1AP | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1243431164, COSV100723512; called by muse, varscan2
- NOX5 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs762907300, COSV52986467, COSV99534460; called by muse, mutect2
- NPAS2 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1164099139, COSV100176641; called by muse, mutect2, varscan2
- NPEPL1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100622543; called by muse, varscan2
- NPY2R | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100279845; called by muse, mutect2, varscan2
- NPY5R | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); catalogued as COSV100642879; called by muse, mutect2, varscan2
- NRXN1 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100456277; called by muse, mutect2, varscan2
- NRXN2 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99635240; called by muse, mutect2, varscan2
- NT5C1B | c.1753G>A p.D585N (on ENST00000359846 / NM_001199086.2; = p.D525N on NM_033253.4) | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410196; called by muse, mutect2, varscan2
- NTNG1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV99638752; called by muse, mutect2, varscan2
- NTRK3 | c.2492C>T p.T831I (on ENST00000360948 / NM_001012338.2; = p.T817I on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1378163546, COSV100713461, COSV62309553; called by muse, mutect2
- NTRK3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV58135845; called by muse, mutect2
- NUP107 | c.1856A>G p.H619R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99971952; called by muse, mutect2, varscan2
- NUTM2G | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs896995212, COSV100672929, COSV63617159; called by muse, mutect2, varscan2
1,316 further variants in this file (590 protein-altering or splice-affecting, 677 silent, 49 other) are not listed here.
